Somatic mutation profile of tumor specimen TCGA-EJ-A8FU-01A (aliquot TCGA-EJ-A8FU-01A-11D-A364-08) from TCGA case TCGA-EJ-A8FU, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 64.3 years (23,472 days).
Specimen TCGA-EJ-A8FU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 551a324e-a0a5-473f-9f64-09474ff117e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-A8FU-10A (Blood Derived Normal), aliquot TCGA-EJ-A8FU-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c23f2928-1cc8-4062-b0e8-c08445a2902b

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCG2 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.751); catalogued as COSV99419970; called by muse, mutect2
- FBXO21 | c.383G>A p.C128Y | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV100401844; called by muse, mutect2
- LRP5L | n.529G>C | RNA (SNP) | VAF 5/54 reads (9%) | catalogued as COSV101292817; called by muse, mutect2
